RC case RC-B5DB — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/51d52006-4c7e-4d4f-8b62-38dd8a0ef8fd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1961; Vital status: Dead; Days to death: 602 days (1.6 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (3)
1. Prolymphocytic leukemia, T-cell type (the primary disease): ICD-O-3 morphology code: 9834/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 57.2 years (20,902 days); Year of diagnosis: 2018; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Lymph node, NOS / Lymph Node, Para-Aortic / Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 2.6 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ruxolitinib; Initial disease status: Initial Diagnosis; Days to treatment start: 51 days; Days to treatment end: 130 days; Number of cycles: 3; Treatment outcome: Partial Response; Reason treatment ended: Other; Clinical trial indicator: Yes; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Initial Diagnosis; Days to treatment start: 131 days; Days to treatment end: 170 days; Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Fludarabine + Mitoxantrone; Initial disease status: Initial Diagnosis; Days to treatment start: 229 days; Days to treatment end: 229 days; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 259 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ruxolitinib; Initial disease status: Progressive Disease; Days to treatment start: 379 days (1.0 years); Days to treatment end: 540 days (1.5 years); Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ruxolitinib + Tofacitinib; Initial disease status: Progressive Disease; Days to treatment start: 539 days (1.5 years); Days to treatment end: 548 days (1.5 years); Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab + Venetoclax; Initial disease status: Progressive Disease; Days to treatment start: 550 days (1.5 years); Days to treatment end: 589 days (1.6 years); Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Recurrence (histology not recorded by GDC). Age at diagnosis: 58.2 years (21,274 days); Days to diagnosis: 372 days (1.0 years).
3. Progression (histology not recorded by GDC). Age at diagnosis: 58.7 years (21,442 days); Days to diagnosis: 540 days (1.5 years).

Follow-up (6 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100.
- Days to follow up: 112 days; Disease response: Partial Response.
- Days to follow up: 295 days; Disease response: Tumor Free.
- Day 372 (recurrence): Progression or recurrence: Yes; Days to recurrence: 372 days (1.0 years).
- Day 540 (progression): Progression or recurrence: Yes; Days to progression: 540 days (1.5 years).
- Day 602 (end of treatment course 1): Imaging type: PET; Imaging result: Positive.

Molecular and laboratory tests
- Lactate Dehydrogenase 253 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus: Negative [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 103 kg; Height: 175 cm; BMI: 33.6.
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypercholesterolemia / Hypertension / Reactive Airway Disease / Other / Migraine.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample RC-B5DB-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B5DB-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
